Somatic mutation profile of tumor specimen TCGA-IG-A4QT-01A (aliquot TCGA-IG-A4QT-01A-21D-A27G-09) from TCGA case TCGA-IG-A4QT, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, keratinizing, NOS; Tissue or organ of origin: Thoracic esophagus; AJCC pathologic stage: Stage IIA; Tumor grade: G2; Age at diagnosis: 56.1 years (20,506 days).
Specimen TCGA-IG-A4QT-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1f6029d0-37de-44c7-8ba3-8c75041fdc4a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-IG-A4QT-10A (Blood Derived Normal), aliquot TCGA-IG-A4QT-10A-02D-A27G-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/153f1043-12e9-4e99-a640-80b760fe7cc0

The open-access MAF lists 3 somatic variants for this specimen: 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 2, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CILP2 | c.3145C>T p.L1049= | Silent (SNP) | VAF 3/49 reads (6%) | called by muse, mutect2
- RELN | c.5478G>A p.G1826= | Silent (SNP) | VAF 5/46 reads (11%) | called by muse, mutect2
- SERPINA13P | n.721G>T | RNA (SNP) | VAF 4/30 reads (13%) | called by muse, mutect2
